Somatic mutation profile of tumor specimen 0DJO5L from CCDI case PBBXGA, project CCDI-MCI: Molecular Characterization Initiative (MCI). Sex at birth: female; Primary diagnosis: Neoplasm, uncertain whether benign or malignant; Tissue or organ of origin: Brain, NOS; Age at diagnosis: 1.2 years (450 days).
Specimen 0DJO5L: Tissue type: Tumor; Specimen type: Solid Tissue; Preservation method: Frozen.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 41a98132-5626-432e-a880-4aeee1590449.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen 0DJO4S (Peripheral Whole Blood; tissue type Normal); read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/f0b6e9e4-7361-43dc-8c80-ec34b4be7c6b

The open-access MAF lists 4 somatic variants for this specimen: 3 protein-altering or splice-affecting, 1 silent.
By variant classification: Nonsense Mutation 2, Silent 1, Missense Mutation 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- CCDC88B | c.2002C>T p.Q668* | Nonsense Mutation (SNP) | VAF 33/343 reads (10%) | catalogued as COSV100105745; called by muse, mutect2, varscan2
- HNRNPA1L2 | c.586C>T p.R196* | Nonsense Mutation (SNP) | VAF 234/738 reads (32%) | catalogued as rs566360923; called by muse, mutect2, varscan2
- LOXHD1 | c.344C>T p.T115M | Missense Mutation (SNP) | VAF 178/422 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs977671032; called by muse, mutect2, varscan2
- AP002512.3 | c.537C>T p.N179= | Silent (SNP) | VAF 236/509 reads (46%) | catalogued as rs749194186, COSV54406835; called by muse, mutect2, varscan2
